Somatic mutation profile of tumor specimen TARGET-30-PAIMDT-01A (aliquot TARGET-30-PAIMDT-01A-01W) from TARGET case TARGET-30-PAIMDT, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 3.9 years (1,408 days).
Specimen TARGET-30-PAIMDT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 436c2218-b743-4b4a-9d00-ec788ea3f086.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIMDT-10A (Blood Derived Normal), aliquot TARGET-30-PAIMDT-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43da963d-2cd3-437a-86b3-5246af0884df

The open-access MAF lists 27 somatic variants for this specimen: 14 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 12, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANPEP | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55596145; called by muse, mutect2, varscan2
- AXDND1 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177063777; called by muse, mutect2
- COL4A3 | c.4157C>G p.P1386R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as COSV67421535; called by muse, mutect2, varscan2
- DENND2C | c.607T>G p.C203G | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV67924527; called by muse, mutect2, varscan2
- DRP2 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65812189; called by muse, mutect2, varscan2
- EIF2AK2 | c.786-2A>G p.X262_splice | Splice Site (SNP) | VAF 49/98 reads (50%) | catalogued as COSV51799840; called by muse, mutect2, varscan2
- IL16 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57269242; called by muse, mutect2, varscan2
- LRRCC1 | c.2404C>G p.R802G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV64483890, COSV64486397; called by muse, mutect2, varscan2
- MDH2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV104410364, COSV59885489; called by muse, mutect2, varscan2
- RPH3A | c.1571G>A p.R524H (on ENST00000389385 / NM_001143854.2; = p.R520H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs757435949, COSV66992809; called by muse, mutect2, varscan2
- SPRR1A | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 130/301 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1387473574, COSV61081761; called by muse, mutect2, varscan2
- SYCP2L | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV51658587; called by muse, mutect2, varscan2
- ABCA9 | c.2291G>T p.R764M | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2
- ATP10B | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- ACKR2 | c.315C>T p.S105= | Silent (SNP) | VAF 199/268 reads (74%) | catalogued as rs747015850, COSV56180894, COSV99825359; called by muse, mutect2, varscan2
- ANKRD17 | c.2871G>A p.A957= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs755293221; called by muse, mutect2
- ARHGEF40 | c.2085G>A p.R695= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53882169; called by muse, mutect2
- EPB41L3 | c.1881C>A p.I627= | Silent (SNP) | VAF 77/405 reads (19%) | catalogued as rs1314452945, COSV59471514; called by muse, mutect2, varscan2
- GPC2 | c.981T>G p.G327= | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- IGHG2 | c.207G>T p.V69= | Silent (SNP) | VAF 18/233 reads (8%) | called by muse, mutect2
- ISM1 | c.1323C>T p.N441= | Silent (SNP) | VAF 94/187 reads (50%) | catalogued as rs748892925, COSV52607711; called by muse, mutect2, varscan2
- MAN2A1 | c.901C>T p.L301= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as COSV54860132; called by muse, mutect2, varscan2
- MUC16 | c.12657C>A p.P4219= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV67502351; called by muse, mutect2, varscan2
- OSMR | c.1782A>T p.G594= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV57093698; called by muse, mutect2, varscan2
- TMEM132B | c.2142T>G p.P714= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as rs1333236426, COSV54774471; called by muse, mutect2
- WNT3A | c.327G>A p.S109= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs373278590; called by muse, mutect2, varscan2
- HIGD2A | c.*4del | 3'UTR (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
